Somatic mutation profile of tumor specimen MMRF_1656_1_BM_CD138pos (aliquot MMRF_1656_1_BM_CD138pos_T1_KBS5U_L04404) from MMRF case MMRF_1656, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.0 years (25,923 days).
Specimen MMRF_1656_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a244b5c1-fbd3-4cd7-a327-aa2a4339f042.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1656_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1656_1_PB_Whole_C3_KBS5U_L04408; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/997b73a0-90f6-4a94-aeec-be14ba8a9a6b

The open-access MAF lists 93 somatic variants for this specimen: 42 protein-altering or splice-affecting, 12 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, 3'UTR 18, Silent 12, Intron 11, 5'UTR 4, 5'Flank 3, RNA 2, Frame Shift Del 2, Nonsense Mutation 2, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C8B | c.829C>T p.H277Y | Missense Mutation (SNP) | VAF 44/54 reads (81%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs147387692; called by muse, mutect2, varscan2
- GLB1L3 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV101111108; called by muse, mutect2, varscan2
- HABP2 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.097); catalogued as COSV63636488; called by muse, mutect2, varscan2
- HEATR6 | c.1852A>G p.T618A | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as rs1206781450; called by mutect2, varscan2
- HOXB1 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs755351120, COSV53316586, COSV99495463; called by muse, mutect2, varscan2
- IGHJ1 | c.16C>T p.H6Y | Missense Mutation (SNP) | VAF 21/24 reads (88%) | catalogued as rs371876779; called by muse, mutect2, varscan2
- IGHJ2 | c.5G>A p.W2* | Nonsense Mutation (SNP) | VAF 32/38 reads (84%) | catalogued as rs562157905; called by muse, varscan2
- IGHJ4 | c.7G>C p.D3H | Missense Mutation (SNP) | VAF 33/41 reads (80%) | PolyPhen possibly damaging (0.902); catalogued as rs532078280; called by muse, mutect2, varscan2
- IGHV2-70 | c.294G>C p.Q98H | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs371102764; called by muse, varscan2
- IGHV2-70 | c.136T>A p.F46I | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as rs368473747; called by muse, varscan2
- IGHV2-70 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs530408879; called by muse, varscan2
- IGLV3-1 | c.203A>G p.Q68R | Missense Mutation (SNP) | VAF 38/44 reads (86%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs373323725; called by muse, varscan2
- IGLV3-25 | c.161A>G p.Y54C | Missense Mutation (SNP) | VAF 59/101 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as rs377194630; called by muse, mutect2, varscan2
- KIAA0319 | c.2900T>C p.I967T | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs758963733; called by muse, mutect2, varscan2
- KRT86 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs1397640624; called by muse, mutect2, varscan2
- MICALL2 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1304638450; called by muse, mutect2, varscan2
- MYEF2 | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 53/239 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51047982, COSV51055213; called by muse, mutect2, varscan2
- NME8 | c.607C>T p.R203* | Nonsense Mutation (SNP) | VAF 46/117 reads (39%) | catalogued as rs142023810; called by muse, mutect2, varscan2
- PCDHA11 | c.1660G>A p.V554M | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV56493477; called by muse, varscan2
- TTC25 | c.118C>T p.L40F | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs554993453; called by muse, mutect2, varscan2
- ZNF25 | c.1193A>G p.Y398C | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs758284706; called by muse, mutect2, varscan2
- BCR | c.212A>G p.D71G | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BTBD8 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); called by muse, mutect2
- CCDC82 | c.1598_1599del p.F533Cfs*10 | Frame Shift Del (DEL) | VAF 91/351 reads (26%) | called by mutect2, pindel, varscan2
- EML6 | c.3340A>G p.T1114A | Missense Mutation (SNP) | VAF 72/177 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- KMT2C | c.12877C>T p.P4293S | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); called by muse, mutect2
- MDM4 | c.166T>G p.L56V | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MYLPF | c.17C>A p.A6D | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- MYO19 | c.2511A>T p.E837D (on ENST00000614623 / NM_001163735.1; = p.E637D on NM_025109.5) | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MYO5C | c.1025G>T p.G342V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- PCF11 | c.3607T>G p.F1203V | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PCNX3 | c.1943T>A p.V648E | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PLEKHG1 | c.1966G>T p.D656Y | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- POGZ | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 58/461 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.787); called by muse, mutect2
- PTCHD4 | c.1063G>T p.A355S | Missense Mutation (SNP) | VAF 57/106 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- RNF146 | c.292del p.S98Vfs*42 (on ENST00000368314 / NM_001242850.2; = p.S97Vfs*42 on NM_030963.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 37/110 reads (34%) | called by mutect2, pindel, varscan2
- TM7SF3 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 101/234 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- TMEM221 | c.563C>A p.P188Q | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- TMPRSS11D | c.443A>C p.N148T | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TSHZ3 | c.2681G>A p.R894H | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- YY1 | c.1016A>C p.K339T | Missense Mutation (SNP) | VAF 87/207 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZNF292 | c.2477dup p.H827Afs*4 | Frame Shift Ins (INS) | VAF 56/144 reads (39%) | called by mutect2, varscan2
- ADAM2 | c.1626C>T p.C542= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs201864039, COSV55866929, COSV99696491; called by mutect2, varscan2
- ASXL3 | c.4530C>T p.S1510= | Silent (SNP) | VAF 37/150 reads (25%) | catalogued as rs566372551; called by muse, mutect2, varscan2
- ATP9B | c.2802C>T p.F934= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs764301018, COSV100303708; called by muse, mutect2, varscan2
- ERAP2 | c.1443C>T p.Y481= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs773321134; called by muse, mutect2, varscan2
- IGLV3-27 | c.66G>A p.E22= | Silent (SNP) | VAF 45/108 reads (42%) | catalogued as rs573159010; called by muse, mutect2, varscan2
- MZF1 | c.1849A>C p.R617= | Silent (SNP) | VAF 20/67 reads (30%) | called by muse, mutect2, varscan2
- NCKAP5 | c.3100C>T p.L1034= | Silent (SNP) | VAF 28/57 reads (49%) | called by muse, mutect2, varscan2
- PCDH9 | c.2499C>T p.T833= | Silent (SNP) | VAF 60/125 reads (48%) | catalogued as rs1253905807; called by muse, mutect2, varscan2
- RTN4 | c.2928A>G p.E976= | Silent (SNP) | VAF 26/67 reads (39%) | called by muse, mutect2, varscan2
- SHROOM4 | c.3900C>T p.G1300= | Silent (SNP) | VAF 85/105 reads (81%) | catalogued as rs1049181461; called by muse, mutect2, varscan2
- SLC6A17 | c.1416C>A p.G472= | Silent (SNP) | VAF 34/42 reads (81%) | called by muse, mutect2, varscan2
- ZNF451 | c.642T>C p.C214= | Silent (SNP) | VAF 13/21 reads (62%) | called by muse, mutect2, varscan2
- C14orf132 | c.*6209dup | 3'UTR (INS) | VAF 11/31 reads (35%) | catalogued as rs1236551791; called by mutect2, pindel, varscan2
- CACNA1B | c.5223-1596A>G | Intron (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- CALM2 | chr2:47176572 G>T | 5'Flank (SNP) | VAF 19/41 reads (46%) | catalogued as rs899633621; called by muse, mutect2, varscan2
- CARMIL1 | c.-71A>G | 5'UTR (SNP) | VAF 67/135 reads (50%) | called by muse, mutect2, varscan2
- CCAR2 | c.585-172_585-169del | Intron (DEL) | VAF 17/36 reads (47%) | called by mutect2, pindel, varscan2
- CDH7 | chr18:65885235 G>A | 3'Flank (SNP) | VAF 3/16 reads (19%) | catalogued as rs1480310586; called by muse, mutect2
- CDK7 | c.*205T>C | 3'UTR (SNP) | VAF 26/117 reads (22%) | called by muse, mutect2, varscan2
- COA1 | c.-38-53G>A | Intron (SNP) | VAF 41/90 reads (46%) | called by muse, mutect2, varscan2
- COLQ | c.107-8943G>A | Intron (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- CREB3L2 | c.103-25076G>A | Intron (SNP) | VAF 55/124 reads (44%) | called by muse, mutect2, varscan2
- CTNNA2 | c.*332T>G | 3'UTR (SNP) | VAF 31/60 reads (52%) | called by muse, mutect2, varscan2
- FANCD2P2 | n.666T>G | RNA (SNP) | VAF 6/14 reads (43%) | called by muse, varscan2
- GRIK2 | c.*1299C>A | 3'UTR (SNP) | VAF 13/38 reads (34%) | called by muse, mutect2, varscan2
- GRTP1 | c.*230G>T | 3'UTR (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- IMMP2L | c.*394A>G | 3'UTR (SNP) | VAF 53/126 reads (42%) | called by muse, mutect2, varscan2
- LYNX1 | c.*407G>A | 3'UTR (SNP) | VAF 57/131 reads (44%) | catalogued as rs13267427; called by muse, mutect2, varscan2
- MAP9 | c.1822-2249C>G | Intron (SNP) | VAF 114/223 reads (51%) | called by muse, mutect2, varscan2
- MED10 | c.*469G>A | 3'UTR (SNP) | VAF 59/189 reads (31%) | called by muse, mutect2, varscan2
- MED22 | c.-227G>A | 5'UTR (SNP) | VAF 41/162 reads (25%) | called by muse, mutect2, varscan2
- NADK2 | c.861-1414C>A | Intron (SNP) | VAF 20/66 reads (30%) | called by muse, mutect2, varscan2
- NPR3 | chr5:32710153 C>A | 5'Flank (SNP) | VAF 64/185 reads (35%) | called by muse, mutect2, varscan2
- OPA1 | chr3:193593146 G>T | 5'Flank (SNP) | VAF 51/102 reads (50%) | called by muse, mutect2, varscan2
- PAPPA2 | c.*977T>C | 3'UTR (SNP) | VAF 29/113 reads (26%) | called by muse, mutect2, varscan2
- PHF24 | c.*3087A>C | 3'UTR (SNP) | VAF 49/91 reads (54%) | called by muse, mutect2, varscan2
- PKHD1 | c.10156+23163T>A | Intron (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- POU3F3 | c.*651C>T | 3'UTR (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- PPM1A | c.*2673C>T | 3'UTR (SNP) | VAF 37/74 reads (50%) | called by muse, mutect2, varscan2
- RHOU | c.*142G>A | 3'UTR (SNP) | VAF 89/140 reads (64%) | called by muse, mutect2, varscan2
- RNF213 | c.*869T>A | 3'UTR (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- SH3BGRL2 | c.*1754del | 3'UTR (DEL) | VAF 12/36 reads (33%) | catalogued as rs982815110; called by mutect2, varscan2
- SH3D19 | c.-206C>T | 5'UTR (SNP) | VAF 29/56 reads (52%) | called by muse, mutect2, varscan2
- SLC12A2 | c.*2194A>T | 3'UTR (SNP) | VAF 64/202 reads (32%) | called by muse, mutect2, varscan2
- SNRNP200 | c.*251G>A | 3'UTR (SNP) | VAF 42/98 reads (43%) | called by muse, mutect2, varscan2
- SNX29P1 | n.708G>C | RNA (SNP) | VAF 47/180 reads (26%) | called by muse, mutect2, varscan2
- TRIM27 | c.920-36C>T | Intron (SNP) | VAF 29/81 reads (36%) | catalogued as rs781360991; called by muse, mutect2, varscan2
- UNC5A | c.721+666G>A | Intron (SNP) | VAF 6/18 reads (33%) | catalogued as rs559693536; called by muse, varscan2
- VILL | c.-86-120C>T | Intron (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- ZNF30 | c.-40A>C | 5'UTR (SNP) | VAF 124/215 reads (58%) | catalogued as COSV100340291; called by muse, mutect2
- ZNF529 | c.*118T>G | 3'UTR (SNP) | VAF 8/16 reads (50%) | called by muse, varscan2
